Somatic mutation profile of tumor specimen 0DOLVA from CCDI case PBCCGN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.9 years (7,284 days).
Specimen 0DOLVA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72fbba85-b518-48cc-8552-aeb7e7e0f080.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOLUQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2475a08e-3622-49f7-9ab2-c2b02f0237ee

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH9 | c.2201C>T p.S734L | Missense Mutation (SNP) | VAF 36/890 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50251836, COSV50254045; called by muse, mutect2
- MAP9 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 126/372 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.889); catalogued as COSV60905695; called by muse, mutect2, varscan2
- NECTIN1 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 18/555 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50599247; called by muse, mutect2
- SOWAHA | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 35/686 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1404494029; called by muse, mutect2
- OR9A2 | c.192C>A p.H64Q | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- PIK3R6 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 30/549 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- SDR16C5 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 43/552 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.153); called by muse, mutect2
- GNA12 | c.741C>T p.S247= | Silent (SNP) | VAF 137/375 reads (37%) | catalogued as COSV51741908; called by muse, mutect2, varscan2
